Somatic mutation profile of tumor specimen CDDP-ACL2-TTP1-A (aliquot CDDP-ACL2-TTP1-A-1-0-D-A572-36) from CDDP_EAGLE case CDDP-ACL2, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 62 years.
Specimen CDDP-ACL2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 559495a5-32af-4a85-af47-ad1025369257.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ACL2-NB1-A (Blood Derived Normal), aliquot CDDP-ACL2-NB1-A-1-0-D-A572-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1847ef0-3031-43e3-96d5-ba10c4fcb3ce

The open-access MAF lists 255 somatic variants for this specimen: 178 protein-altering or splice-affecting, 41 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 41, Intron 18, Nonsense Mutation 16, Splice Site 6, RNA 5, 3'Flank 4, 5'UTR 4, 3'UTR 3, Frame Shift Del 3, 5'Flank 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 77/169 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1997A>T p.K666M | Missense Mutation (SNP) | VAF 113/263 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374250186, COSV59205833, COSV59206062, COSV59207657; called by muse, mutect2, varscan2
- STK11 | c.250A>T p.K84* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | hotspot (GDC flag); catalogued as rs137853076, CM981866, COSV58820372; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.1777C>A p.R593S | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs28381914; called by muse, mutect2, varscan2
- ADGRL3 | c.4146C>A p.Y1382* (on ENST00000506720 / NM_001322402.2; = p.Y1271* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 18/93 reads (19%) | catalogued as rs747983425; called by muse, mutect2, varscan2
- ANK1 | c.4538-1G>T p.X1513_splice | Splice Site (SNP) | VAF 28/83 reads (34%) | catalogued as COSV99225677; called by muse, mutect2, varscan2
- ASMT | c.444G>T p.R148S | Missense Mutation (SNP) | VAF 82/431 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.794); catalogued as rs771416924; called by muse, mutect2, varscan2
- BCR | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.525); catalogued as rs745732482; called by muse, mutect2, varscan2
- BEST3 | c.1169C>A p.S390Y | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58302709; called by muse, varscan2
- CCDC172 | c.317A>G p.D106G | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as COSV100319614; called by muse, mutect2, varscan2
- CCM2 | c.379G>T p.G127W | Missense Mutation (SNP) | VAF 53/194 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51848678, COSV99347757; called by muse, mutect2, varscan2
- CD177 | c.698C>A p.S233* | Nonsense Mutation (SNP) | VAF 29/123 reads (24%) | catalogued as COSV65121310; called by muse, mutect2, varscan2
- CEP120 | c.2659G>T p.A887S | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV100071096; called by muse, mutect2, varscan2
- CEP57 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.642); catalogued as COSV57687799; called by muse, mutect2, varscan2
- CPS1 | c.173G>A p.G58D | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM114302; called by muse, mutect2, varscan2
- DAPK1 | c.2101A>C p.T701P | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs763518301, COSV63789090, COSV63792616; called by muse, mutect2, varscan2
- DEFA5 | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs776287950, COSV57962576; called by muse, mutect2
- DNAH9 | c.2539G>T p.E847* | Nonsense Mutation (SNP) | VAF 27/80 reads (34%) | catalogued as COSV52332598; called by muse, mutect2, varscan2
- DST | c.5701A>G p.I1901V | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.182); catalogued as rs575202711; called by muse, mutect2, varscan2
- E2F4 | c.1145G>T p.R382L | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV62607140; called by muse, mutect2, varscan2
- EBF3 | c.155C>G p.A52G | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV62472308; called by muse, mutect2, varscan2
- EP400 | c.6312G>A p.M2104I | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV57766590; called by muse, mutect2, varscan2
- EXOC3L1 | c.165C>A p.S55R | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as rs1567685704, COSV100104076; called by muse, mutect2, varscan2
- FLG | c.9987C>A p.D3329E | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.549); catalogued as COSV64241106; called by muse, mutect2, varscan2
- IL2RB | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53427773; called by muse, mutect2, varscan2
- KAT8 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.548); catalogued as COSV54898620; called by muse, mutect2, varscan2
- KLK15 | c.491C>A p.P164Q | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56828544; called by muse, mutect2, varscan2
- KRTAP13-1 | c.421G>C p.G141R | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV100819893; called by muse, mutect2, varscan2
- MMP8 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.56); catalogued as rs867528231, COSV52632662; called by muse, mutect2, varscan2
- MRPS12 | c.224C>A p.S75* | Nonsense Mutation (SNP) | VAF 36/91 reads (40%) | catalogued as rs1471198925; called by muse, mutect2, varscan2
- MYBPC2 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 58/134 reads (43%) | catalogued as COSV63099933; called by muse, mutect2, varscan2
- NLRP4 | c.1550C>A p.A517E | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV56711220; called by muse, mutect2, varscan2
- PCDHB12 | c.1897C>A p.R633S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV53392994, COSV99507848; called by mutect2, varscan2
- PCDHGB7 | c.1648G>T p.V550L | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.553); catalogued as COSV53907917; called by muse, mutect2, varscan2
- PHKB | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs887780102; called by muse, mutect2, varscan2
- PIRT | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV74119918; called by muse, mutect2, varscan2
- PLIN3 | c.915C>G p.N305K | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.52); catalogued as rs774902476; called by muse, mutect2, varscan2
- RAC2 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.087); catalogued as COSV50774405; called by muse, varscan2
- SCN3A | c.2011C>T p.P671S | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as COSV51826757; called by muse, mutect2, varscan2
- SEMA4C | c.2263G>A p.G755S | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.06); catalogued as rs376941141; called by muse, mutect2, varscan2
- SH3PXD2B | c.2034G>T p.K678N | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV100288439; called by muse, mutect2, varscan2
- SHANK1 | c.2041del p.A681Pfs*45 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | catalogued as COSV53242231; called by pindel, varscan2
- SMC1A | c.2828C>T p.S943L | Missense Mutation (SNP) | VAF 79/294 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100447201; called by muse, varscan2
- SPATA6 | c.994C>G p.P332A | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.981); catalogued as COSV100892987; called by muse, mutect2, varscan2
- TBC1D16 | c.82G>T p.G28W | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as COSV104407569; called by muse, mutect2, varscan2
- TCHH | c.4675G>T p.E1559* | Nonsense Mutation (SNP) | VAF 109/308 reads (35%) | catalogued as COSV64276945; called by muse, mutect2, varscan2
- TMPRSS11E | c.243G>C p.Q81H | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV100542137, COSV100542559; called by muse, mutect2, varscan2
- TUBB8B | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 88/395 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1309736831; called by muse, mutect2, varscan2
- UBQLN3 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs747573404, COSV100293502; called by muse, mutect2, varscan2
- UNC80 | c.3904C>A p.L1302M | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.79); catalogued as COSV99778419; called by muse, mutect2, varscan2
- VCAN | c.8866G>T p.A2956S | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs1409484279; called by muse, mutect2, varscan2
- ZNF534 | c.434G>T p.C145F (on ENST00000332323 / NM_001143939.3; = p.C132F on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.138); catalogued as COSV99989932; called by muse, mutect2, varscan2
- ABI3BP | c.193A>T p.S65C | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ACTN2 | c.616-1G>T p.X206_splice | Splice Site (SNP) | VAF 32/153 reads (21%) | called by muse, mutect2, varscan2
- ADGRF4 | c.918C>G p.H306Q | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ADGRL2 | c.3213A>G p.I1071M (on ENST00000370717 / NM_001366005.1; = p.I1058M on NM_012302.4) | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- AFF2 | c.1792C>G p.P598A | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- AFF2 | c.1793C>A p.P598Q | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- AKAP13 | c.6920A>G p.D2307G (on ENST00000394518 / NM_007200.5; = p.D2311G on NM_006738.6) | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP4 | c.1778C>G p.A593G | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AKAP4 | c.1018G>T p.V340L | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.097); called by muse, varscan2
- ANKLE2 | c.2351G>T p.G784V | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- ASTN1 | c.2772C>G p.H924Q | Missense Mutation (SNP) | VAF 67/320 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCL11B | c.2228A>T p.H743L (on ENST00000357195 / NM_001282237.2; = p.H672L on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/284 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BCR | c.360G>T p.E120D | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- BEND2 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- BICRA | c.3067G>T p.A1023S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- BTBD1 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- C22orf15 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CADM2 | c.563T>A p.L188Q (on ENST00000407528 / NM_001167674.2; = p.L190Q on NM_153184.4) | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- CALCRL | c.727G>T p.V243L | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CAMK4 | c.647G>T p.C216F | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CASS4 | c.529C>A p.P177T | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CASS4 | c.530C>A p.P177H | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCNY | c.459+1G>A p.X153_splice | Splice Site (SNP) | VAF 26/97 reads (27%) | called by muse, mutect2, varscan2
- CEP152 | c.2773A>T p.K925* | Nonsense Mutation (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
- CFAP47 | c.9103G>C p.D3035H | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); called by muse, mutect2
- CHD8 | c.4135A>G p.K1379E (on ENST00000646647 / NM_001170629.2; = p.K1100E on NM_020920.4) | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CHRM2 | c.167C>A p.T56N | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CNOT4 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.376); called by mutect2, varscan2
- COL18A1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL20A1 | c.1622G>T p.G541V | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- COL5A2 | c.4444G>T p.V1482F | Missense Mutation (SNP) | VAF 138/332 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- COL5A2 | c.1700G>T p.G567V | Missense Mutation (SNP) | VAF 54/270 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL8A1 | c.1214G>T p.G405V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CRYBB1 | c.579G>A p.W193* | Nonsense Mutation (SNP) | VAF 22/154 reads (14%) | called by muse, mutect2, varscan2
- CST8 | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- CUX1 | c.3031G>T p.G1011C | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP1A1 | c.247del p.V83Wfs*4 | Frame Shift Del (DEL) | VAF 24/86 reads (28%) | called by mutect2, pindel*, varscan2
- DCHS1 | c.8612G>T p.R2871L | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- DDX53 | c.1495G>T p.G499C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX56 | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKK | c.1199A>C p.Q400P | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DHRS2 | c.554A>G p.Y185C | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- F8 | c.1886C>A p.A629D | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- FAM234B | c.983A>G p.Y328C | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT3 | c.3801C>A p.D1267E | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- FOLH1 | c.927G>A p.M309I | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FYB1 | c.1193C>A p.S398Y | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- GRP | c.231G>T p.W77C | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HCFC2 | c.683-31_690del p.X228_splice | Splice Site (DEL) | VAF 34/62 reads (55%) | called by mutect2, pindel
- HECTD1 | c.6395G>C p.R2132T | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- HTATSF1 | c.115G>T p.D39Y | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGKV1D-42 | c.201G>T p.K67N | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.423); called by muse, varscan2
- IRF6 | c.380-10_380-2del p.X127_splice | Splice Site (DEL) | VAF 20/200 reads (10%) | called by mutect2, pindel
- ITGBL1 | c.782G>T p.W261L | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- ITIH6 | c.2007C>A p.Y669* | Nonsense Mutation (SNP) | VAF 27/99 reads (27%) | called by muse, mutect2, varscan2
- KCNA4 | c.857A>T p.E286V | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- KEAP1 | c.474dup p.A159Cfs*15 | Frame Shift Ins (INS) | VAF 68/185 reads (37%) | called by mutect2, pindel, varscan2
- KIAA0100 | c.3304G>T p.D1102Y | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1755 | c.425C>A p.P142H | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- KIF1A | c.751G>T p.G251W | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLK7 | c.325C>A p.H109N | Missense Mutation (SNP) | VAF 94/225 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- KMT2B | c.3794T>G p.L1265R | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KRT9 | c.1700G>A p.G567E | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LALBA | c.252G>T p.Q84H | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LDLR | c.608A>C p.H203P | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- LIM2 | c.252G>A p.M84I (on ENST00000596399 / NM_001161748.2; = p.M126I on NM_030657.4) | Missense Mutation (SNP) | VAF 96/261 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRP1B | c.10329T>A p.C3443* | Nonsense Mutation (SNP) | VAF 34/174 reads (20%) | called by muse, mutect2, varscan2
- LRRC8B | c.1258G>T p.D420Y | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- MAEL | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MAPKBP1 | c.2977C>T p.H993Y (on ENST00000456763 / NM_001128608.2; = p.H987Y on NM_014994.3) | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); called by muse, mutect2
- MAT1A | c.778G>A p.G260S | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MBL2 | c.444T>A p.F148L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); called by mutect2, varscan2
- MRAP | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 39/350 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MTMR4 | c.3388G>T p.A1130S | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC22 | c.2957C>T p.T986I | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT deleterious (0.02); called by muse, mutect2, varscan2
- MYO3A | c.2744C>T p.A915V | Missense Mutation (SNP) | VAF 73/348 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- NFASC | c.2839G>T p.D947Y | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLRP3 | c.2713G>T p.V905L | Missense Mutation (SNP) | VAF 39/306 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR13D1 | c.506A>G p.N169S | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.021); called by mutect2, varscan2
- OR4K5 | c.121G>T p.G41* | Nonsense Mutation (SNP) | VAF 38/133 reads (29%) | called by muse, mutect2, varscan2
- OSER1 | c.284G>A p.C95Y | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- OTOGL | c.6119G>T p.C2040F (on ENST00000547103; = p.C2031F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, varscan2
- PAK4 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- PCDHB7 | c.823G>T p.G275W | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCNX4 | c.104G>T p.C35F | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- PFKM | c.310A>G p.N104D | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PIK3R5 | c.1601C>A p.A534E | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKP2 | c.2469G>C p.M823I | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- POC5 | c.1645A>G p.T549A (on ENST00000428202 / NM_001099271.2; = p.T524A on NM_152408.2) | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R13L | c.1041G>T p.Q347H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, varscan2
- PRKCG | c.1825C>G p.R609G | Missense Mutation (SNP) | VAF 72/294 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- PRR23C | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PRRC2C | c.4501G>T p.A1501S (on ENST00000367742; = p.A1499S on NM_015172.4) | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- PTRHD1 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 87/511 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- PYM1 | c.124G>T p.V42F | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RAG2 | c.542G>T p.C181F | Missense Mutation (SNP) | VAF 79/266 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAMP3 | c.101T>A p.L34* | Nonsense Mutation (SNP) | VAF 31/108 reads (29%) | called by muse, mutect2, varscan2
- RBM3 | c.228G>T p.Q76H | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RCSD1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- RNASEL | c.2007G>T p.L669F | Missense Mutation (SNP) | VAF 79/152 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- RPS3 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- RSPO2 | c.722C>A p.A241D | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); called by muse, varscan2
- SCML2 | c.947dup p.E317Gfs*27 | Frame Shift Ins (INS) | VAF 7/30 reads (23%) | called by mutect2, pindel, varscan2
- SDHC | c.227T>C p.I76T | Missense Mutation (SNP) | VAF 36/462 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.147); called by muse, mutect2
- SH3TC2 | c.2930C>G p.P977R | Missense Mutation (SNP) | VAF 86/285 reads (30%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- SLC10A3 | c.415C>A p.L139M | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC6A19 | c.1014C>A p.S338R | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- SMG1 | c.4565C>T p.A1522V | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- SPTA1 | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 85/416 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPTA1 | c.358A>T p.T120S | Missense Mutation (SNP) | VAF 48/282 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SUPT20HL1 | c.1751C>A p.P584Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.035); called by muse, varscan2
- SVEP1 | c.5423G>A p.G1808D | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TGIF2LX | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 42/125 reads (34%) | called by muse, mutect2, varscan2
- THEG | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- THSD7A | c.448del p.E150Kfs*6 | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | called by mutect2, pindel, varscan2
- TSPYL2 | c.1618G>T p.G540C | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- UNC79 | c.5383G>T p.E1795* (on ENST00000393151 / NM_001346218.2; = p.E1618* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 17/78 reads (22%) | called by muse, mutect2, varscan2
- USH2A | c.2692C>A p.Q898K | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- WWC3 | c.377+1G>A p.X126_splice | Splice Site (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- XYLT1 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZNF256 | c.435C>A p.H145Q | Missense Mutation (SNP) | VAF 56/223 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ZNF292 | c.475G>T p.G159W | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF626 | c.650C>A p.T217N | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ZNF679 | c.834C>A p.S278R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by mutect2, varscan2
- ZNF827 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ZXDA | c.87C>A p.H29Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASTN1 | c.553C>A p.R185= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV56079940; called by muse, mutect2, varscan2
- BNIP5 | c.1863C>T p.I621= | Silent (SNP) | VAF 36/149 reads (24%) | called by muse, mutect2, varscan2
- CASK | c.2670C>T p.F890= (on ENST00000378163 / NM_001367721.1; = p.F885= on NM_003688.3) | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as rs773214246, COSV59364492; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDX1 | c.54C>G p.A18= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs1002693095; called by muse, mutect2, varscan2
- CENPI | c.1392T>C p.F464= | Silent (SNP) | VAF 30/102 reads (29%) | called by muse, mutect2, varscan2
- CIC | c.4185G>A p.K1395= | Silent (SNP) | VAF 50/112 reads (45%) | called by muse, mutect2, varscan2
- COL6A1 | c.1437C>T p.G479= | Silent (SNP) | VAF 46/188 reads (24%) | catalogued as rs762625409, COSV62615381; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A2 | c.2862C>T p.N954= | Silent (SNP) | VAF 26/195 reads (13%) | catalogued as rs761975390; called by muse, mutect2, varscan2
- DDX4 | c.1098A>G p.P366= | Silent (SNP) | VAF 44/130 reads (34%) | called by muse, mutect2, varscan2
- FAM83B | c.1191G>T p.V397= | Silent (SNP) | VAF 15/80 reads (19%) | called by muse, mutect2, varscan2
- GAPVD1 | c.3762G>T p.V1254= (on ENST00000394104; = p.V1263= on NM_015635.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- HS3ST3A1 | c.651C>A p.P217= | Silent (SNP) | VAF 18/105 reads (17%) | called by muse, mutect2
- IGLV3-9 | c.114G>A p.R38= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as rs779311639; called by muse, mutect2, varscan2
- LHX2 | c.33G>T p.V11= | Silent (SNP) | VAF 16/102 reads (16%) | called by muse, mutect2, varscan2
- MPL | c.1254C>A p.A418= | Silent (SNP) | VAF 65/211 reads (31%) | called by muse, mutect2, varscan2
- MYBL2 | c.771C>T p.I257= | Silent (SNP) | VAF 57/207 reads (28%) | catalogued as rs199723555, COSV99405963; called by muse, mutect2, varscan2
- MYF6 | c.280C>A p.R94= | Silent (SNP) | VAF 131/318 reads (41%) | catalogued as rs1188507871; called by muse, mutect2, varscan2
- MYOCD | c.660G>T p.A220= | Silent (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- MYOM2 | c.1923G>T p.L641= | Silent (SNP) | VAF 44/144 reads (31%) | called by muse, mutect2, varscan2
- NHSL2 | c.1791A>G p.T597= (on ENST00000510661; = p.T963= on NM_001013627.2) | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1569484410; called by mutect2, varscan2
- NLGN4X | c.2364G>T p.G788= | Silent (SNP) | VAF 57/176 reads (32%) | catalogued as COSV52006116; called by muse, mutect2, varscan2
- NLRP3 | c.2712G>T p.S904= | Silent (SNP) | VAF 41/307 reads (13%) | called by muse, mutect2, varscan2
- PCDHA3 | c.135G>T p.V45= | Silent (SNP) | VAF 115/415 reads (28%) | called by muse, varscan2
- PCDHGB2 | c.1869G>T p.T623= | Silent (SNP) | VAF 28/147 reads (19%) | called by muse, mutect2
- PIKFYVE | c.1410A>T p.I470= | Silent (SNP) | VAF 137/277 reads (49%) | called by muse, mutect2, varscan2
- PLCB4 | c.2301G>T p.L767= | Silent (SNP) | VAF 22/82 reads (27%) | called by muse, mutect2
- PTCH1 | c.3318G>T p.T1106= | Silent (SNP) | VAF 50/143 reads (35%) | called by muse, mutect2, varscan2
- PTPRG | c.1164C>G p.T388= | Silent (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- RAMP3 | c.438G>A p.T146= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs1159516694; called by muse, mutect2
- RPL3L | c.618C>A p.P206= | Silent (SNP) | VAF 34/92 reads (37%) | called by muse, mutect2, varscan2
- SIGLEC12 | c.660C>T p.F220= (on ENST00000291707 / NM_053003.4; = p.F102= on NM_033329.2) | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV52466226; called by muse, mutect2, varscan2
- SKIDA1 | c.201C>A p.L67= | Silent (SNP) | VAF 29/89 reads (33%) | called by muse, mutect2, varscan2
- SLIT1 | c.2727C>T p.A909= | Silent (SNP) | VAF 30/76 reads (39%) | called by muse, varscan2
- SNTB1 | c.657C>G p.S219= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV67328837; called by muse, mutect2, varscan2
- ST8SIA1 | c.870G>T p.V290= | Silent (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- TMTC3 | c.1617A>C p.R539= | Silent (SNP) | VAF 22/192 reads (11%) | called by muse, mutect2
- TTK | c.1473C>T p.F491= | Silent (SNP) | VAF 64/184 reads (35%) | called by muse, varscan2
- UCK2 | c.477G>A p.A159= | Silent (SNP) | VAF 59/179 reads (33%) | catalogued as rs1165427600, COSV100902895; called by muse, mutect2, varscan2
- VWA5B1 | c.2004C>A p.P668= | Silent (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
- ZNF467 | c.735G>A p.P245= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV57372497; called by mutect2, varscan2
- ZNF835 | c.1104C>A p.G368= | Silent (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- AC114490.3 | c.*229G>T | 3'UTR (SNP) | VAF 35/67 reads (52%) | called by muse, mutect2, varscan2
- ARHGAP8 | c.299+278T>C | Intron (SNP) | VAF 7/70 reads (10%) | catalogued as rs1199925933, COSV104396514; called by muse, varscan2
- CABP1 | c.685+19G>T | Intron (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- DCDC1 | c.1221+26280G>T | Intron (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- ENDOV | c.838+264G>A | Intron (SNP) | VAF 21/64 reads (33%) | catalogued as rs1220484155; called by muse, mutect2, varscan2
- FBXO16 | c.136-1553A>G | Intron (SNP) | VAF 8/56 reads (14%) | catalogued as rs1306579790; called by mutect2, varscan2
- FRMPD2B | n.463G>T | RNA (SNP) | VAF 113/678 reads (17%) | catalogued as rs1287800270; called by mutect2, varscan2
- GTF2IRD2P1 | chr7:73269285 C>T | 5'Flank (SNP) | VAF 57/290 reads (20%) | called by muse, mutect2, varscan2
- HK1 | c.28-3315C>T | Intron (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- HSD3B2 | c.307+9G>T | Intron (SNP) | VAF 30/91 reads (33%) | called by muse, mutect2, varscan2
- KLK1 | chr19:50818408 C>T | 3'Flank (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2
- L2HGDH | chr14:50237615 C>A | 3'Flank (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- LIMCH1 | c.936-7579A>G | Intron (SNP) | VAF 16/85 reads (19%) | catalogued as rs760004532; called by muse, mutect2, varscan2
- LTO1 | c.346-692G>C | Intron (SNP) | VAF 32/115 reads (28%) | called by muse, mutect2, varscan2
- MFRP | chr11:119346498 C>T | 5'Flank (SNP) | VAF 69/211 reads (33%) | called by muse, mutect2, varscan2
- MYH16 | n.2916C>A | RNA (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- NEU4 | c.457+388C>G | Intron (SNP) | VAF 56/117 reads (48%) | called by muse, mutect2, varscan2
- PACRGL | c.609+2607G>T | Intron (SNP) | VAF 32/120 reads (27%) | called by muse, mutect2, varscan2
- PCID2 | c.-2C>T | 5'UTR (SNP) | VAF 32/111 reads (29%) | called by muse, mutect2, varscan2
- PDE4D | c.455+124886C>T | Intron (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2
- PLCE1 | c.1207-43014C>A | Intron (SNP) | VAF 28/108 reads (26%) | called by muse, mutect2, varscan2
- PRPS2 | c.-27G>A | 5'UTR (SNP) | VAF 14/108 reads (13%) | catalogued as rs751983412; called by mutect2, varscan2
- PTENP1 | n.966G>A | RNA (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- RAI14 | c.36+29124T>A | Intron (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- RFLNA | c.-5C>G | 5'UTR (SNP) | VAF 5/8 reads (63%) | catalogued as rs1280856958; called by mutect2, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 12/120 reads (10%) | catalogued as rs910081914; called by muse, mutect2
- RNU7-115P | chr17:64822317 C>A | 3'Flank (SNP) | VAF 79/303 reads (26%) | called by muse, mutect2, varscan2
- SAMD11 | c.1801-31C>T | Intron (SNP) | VAF 12/93 reads (13%) | catalogued as rs376618121; called by mutect2, varscan2
- SLC22A23 | c.1703+1557A>T | Intron (SNP) | VAF 23/140 reads (16%) | called by muse, varscan2
- SPATA31C2 | n.2432C>A | RNA (SNP) | VAF 15/101 reads (15%) | called by muse, mutect2, varscan2
- ST8SIA3 | c.-6C>A | 5'UTR (SNP) | VAF 78/245 reads (32%) | called by muse, mutect2, varscan2
- TMEM135 | c.*2395C>T | 3'UTR (SNP) | VAF 6/32 reads (19%) | called by mutect2, varscan2
- TTC12 | chr11:113368452 G>T | 3'Flank (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
- TUBB4AP1 | n.545C>A | RNA (SNP) | VAF 26/115 reads (23%) | called by muse, mutect2, varscan2
- UBR7 | c.*948C>G | 3'UTR (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- ZFHX3 | c.-897+3547C>A | Intron (SNP) | VAF 63/200 reads (32%) | called by muse, mutect2, varscan2
